Somatic mutation profile of tumor specimen BA2069D (aliquot aq-BA2069D) from BEATAML1.0 case 2179, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with t(9;11)(p22;q23), MLLT3-MLL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.3 years (20,204 days).
Specimen BA2069D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36bfa4c9-03c9-4cb0-9d54-f09dfc8f05d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2797D (Solid Tissue Normal), aliquot aq-BA2797D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d57a772-3921-41d8-9f8e-3ede4e9dc0b0

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC2A8 | c.185C>A p.P62Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as rs1455859456, COSV59228038; called by muse, mutect2
- EDC4 | c.3023C>A p.A1008E | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.462); called by muse, mutect2
